Surgical pathology report (de-identified scan), TCGA case TCGA-3H-AB3T, project TCGA-MESO (Mesothelioma), tissue source site MD Anderson Cancer Center, specimen TCGA-3H-AB3T-01A (Primary Tumor).

Accession: [REDACTED]
Specimen Date/Time:

DIAGNOSIS

(A) RIGHT CHEST WALL MASS, BIOPSY:

MALIGNANT BIPHASIC TUMOR CONSISTENT WITH MESOTHELIOMA.

ICD-O.3
Mesothelioma, biphasic
malignant 9053/3
Site C8CF Pleura NOS C38.4
path Chest wall, soft tissue C49.5
JW 6/13/14

GROSS DESCRIPTION

(A) RIGHT CHEST WALL MASS – A single unoriented red-tan soft tissue fragment (0.8 x 0.6 x 0.4 cm). The entire specimen submitted for frozen section evaluation, telfa side down in A.

*FS/DX: MALIGNANT NEOPLASM, DEFER TO PERMANENT CLASSIFICATION.

CLINICAL HISTORY

Right lung mesothelioma.

SNOMED CODES

T-D3050, M-90503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 632d3179-d4f4-49e4-b9d0-5903df587172 (TCGA-3H-AB3T.4F0240DA-BF51-4D8D-A378-1B39EEFD5FEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).